Surgical pathology report (de-identified scan), TCGA case TCGA-F2-6880, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-6880-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

[REDACTED] TCGA-F2-6880

Diagnosis:

A: "Pancreatic duct margin", biopsy
- Negative for carcinoma.

B: "Uncinate process", biopsy
- Negative for carcinoma.

C: Pancreas/gallbladder/duodenum, pancreaticoduodenectomy

Tumor Histologic Type: adenocarcinoma involving the ampulla; see comment

Histologic grade: well differentiated

Tumor size: 2.2 cm

Extent of invasion:

Peripancreatic soft tissues: involved by adenocarcinoma (C16)

Duodenum: negative for malignancy

Ampulla: involved by adenocarcinoma; see comment (C7)

Lymphatic Invasion: Not identified

Venous Invasion: Not identified

Perineural Invasion: Identified, extensive.

Margins:

Pancreatic neck: negative for malignancy

Bile duct: negative for malignancy; see comment

Posterior pancreatic surface (deep radial margin): negative for malignancy.

Peripancreatic soft tissues: Margin negative for malignancy, but tumor

extends into peripancreatic soft tissue.

Proximal margin: negative for malignancy

Distal margin: negative for malignancy

Regional lymph nodes: One of nine lymph nodes positive for metastatic

adenocarcinoma (1/9), 1 mm in greatest diameter.

[page 2 of 5]
Additional pathologic findings:

- PaIN 3
- Small bowel with mild acute and chronic serositis in the additional bowel segment submitted. The serositis extends to the suture margin; margins appear histologically viable.
- Gallbladder with mild chronic cholecystitis and one lymph node, negative for malignancy (0/1).

AJCC PATHOLOGIC TNM STAGE: pT3 pN1 pMx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

This is a complex case. There is extensive adenocarcinoma, well differentiated, throughout the pancreas and extending into the peri-pancreatic soft tissues.

Additionally, the tumor appears to involve the common bile duct, which shows evidence of high grade pancreatic intraepithelial neoplasia (PaIN-3), although the common bile duct margin is negative for malignancy or dysplasia.

Additionally, the tumor involves the ampulla with very little, if any, dysplasia of the surrounding duodenal epithelium. Dr. has reviewed the slide of the ampullary involvement (C7) and concurs that the adenocarcinoma involves the ampulla. Given the extensive involvement of the rest of the pancreas, however, we favor this tumor being a pancreatic adenocarcinoma involving the ampulla, rather than a primary tumor of the ampulla itself.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested at [REDACTED]
[REDACTED]

FSA1: "Pancreatic duct margin", excision

- Pancreatic tissue with chronic inflammation, no carcinoma identified.

FSB1: "Uncinate process", excision

- Pancreatic tissue with chronic inflammation and fibrosis; no carcinoma identified.
- [REDACTED]

[page 3 of 5]
Frozen Section Pathologist:

Clinical History:

year-old male with a pancreatic mass. The patient also has a two week history of jaundice, diarrhea, and 12 lb. weight loss. A previous bile duct brushing showed no malignant cells.

Gross Description:

Received are three appropriately labeled containers.

Specimen A is additionally labeled "pancreatic duct". The specimen consists of a red-tan soft tissue fragment that measures 2.0 x 1.0 x 0.3 cm, and is submitted entirely in FSA1, NTR.

Specimen B is additionally labeled "uncinate process". The specimen consists of a red-tan soft tissue fragment that measures 1.9 x 0.5 x 0.3 cm, and is submitted entirely in FSB1, NTR.

Specimen C:

Specimen fixation: formalin

Specimen type: standard Whipple with gallbladder

Orientation: With ink: common bile duct = yellow, pancreatic body margin = blue, pancreatic soft tissue = green, uncinate margin = black, gastric margin = orange, and distal duodenum = red.

Tumor location: head of pancreas

Gross appearance of tumor: Mass appears to be a white, firm, poorly circumscribed mass located adjacent to the common bile duct in the head of the pancreas.

Tumor dimensions: approximately 2.2 x 2.0 x 0.9 cm

[page 4 of 5]
Extent of invasion:

Confined/nonconfined to the pancreas: does appear to be extending into

the peripancreatic fat

Involvement of the ampulla: not identified

Involvement of the duodenum: not identified

Involvement of the bile duct: not identified

Involvement of adjacent blood vessels: not identified

Duodenum (if applicable):

Gallbladder (if applicable): appears uninvolved grossly

Stomach (if applicable): uninvolved

Surgical margins:

Pancreas: pancreatic surgical margins appear negative body margin

negative to 0.7 cm uncinata margin negative to 0.4 cm

Bile duct: appears negative to 0.9 cm

Proximal (small bowel or stomach) margin:

Distal (small bowel) margin: widely negative

Peripancreatic soft tissues: appears negative to 0.8 cm

Lymph nodes:

Other remarkable findings: A 1.5 cm length of prepyloric stomach that

measures 3 cm in diameter is submitted and is unremarkable.

Duodenal section

measures approximately 26 cm x 3.5 cm and is lined with yellow-tan, granular

mucosa that is otherwise unremarkable. Additionally a gallbladder is submitted

that measures 7.0 x 4.5 cm with a cystic duct that measures 6.5 cm in length.

The external surface of this gallbladder is red-brown and mottled and smooth.

Wall thickness measures 0.5 cm. Gallbladder mucosa is red-brown and finely

trabeculated with mild cholesterosis. Approximately 10 cc of sludge is

identified within the lumen, however no stones are identified. A free floating

piece of what appears to be small bowel was identified within the container.

[page 5 of 5]
This measures 12 x 2.5 cm. One end of this fragment is stapled while the opposite end is sutured. The external surface is purple-gray and smooth without evidence of perforation or inflammation. Opening of the fragment reveals yellow-tan, finely granular mucosa with normal folding architecture. No abnormalities are identified.

Digital photograph taken: no

Tissue submitted for special investigation: yes tumor to tissue procurement

Block Summary:

- C1 - common bile duct margin
- C2 - pancreatic body margin, en face
- C3 - uncinate margin en face
- C4 - representative sections of mass
- C5 - mass to common bile duct
- C6 - mass to uncinate
- C7 - pancreas to ampulla
- C8 - pancreatic soft tissue margin
- C9 - proximal margin, en face
- C10 - distal margin, en face
- C11 - proximal cystic ducts with periductal lymph node and representative section of gallbladder
- C12 - random bowel fragments, stapled margin
- C13 - random bowel fragment, sutured margin
- C14 - additional representative section of random bowel fragment
- C15 - two peripancreatic lymph node candidates
- C16 - mass to uncinate, perpendicular
- C17 - mass to uncinate, perpendicular
- C18 - additional mass across common bile duct

Source: NCI Genomic Data Commons file 1b1ee74d-c5fa-4005-ae96-193704f593a9 (TCGA-F2-6880.9795D6CE-DD3E-4C89-8295-37266F50AAFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).